Somatic mutation profile of tumor specimen TCGA-X3-A8G4-01A (aliquot TCGA-X3-A8G4-01A-11D-A435-10) from TCGA case TCGA-X3-A8G4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.2 years (12,117 days).
Specimen TCGA-X3-A8G4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bae55a7-695e-4db6-a820-c466391561bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X3-A8G4-10A (Blood Derived Normal), aliquot TCGA-X3-A8G4-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b362048-23c4-47f8-b36e-75fc25a15842

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.8818G>A p.G2940R | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243227858, COSV51922350; called by muse, mutect2, varscan2
- IRX3 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs768270530; called by muse, mutect2, varscan2
- MAP3K2 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760142919, COSV100789247; called by muse, mutect2, varscan2
- MARK3 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 24/217 reads (11%) | catalogued as rs372126503; called by muse, mutect2, varscan2
- POLE4 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs1243286475; called by muse, mutect2, varscan2
- ABCC9 | c.2439T>A p.S813R | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASB9 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB9 | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C2CD4C | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- DDX54 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ENKD1 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ERCC6 | c.4049C>A p.T1350K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FOLR1 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- GARRE1 | c.726_729del p.R243Afs*27 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- IGSF9B | c.3745C>T p.R1249* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- ITGA7 | c.2303C>A p.S768* (on ENST00000555728; = p.S724* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- LRP2 | c.2513+2T>G p.X838_splice | Splice Site (SNP) | VAF 64/214 reads (30%) | called by muse, mutect2, varscan2
- LRRK2 | c.4854T>A p.C1618* | Nonsense Mutation (SNP) | VAF 74/374 reads (20%) | called by muse, mutect2
- MKI67 | c.1621A>G p.M541V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCZ1 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- SLC25A4 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TREX1 | c.260T>C p.L87P (on ENST00000625293 / NM_033629.6; = p.L77P on NM_007248.5) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TULP4 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADAM12 | c.909G>A p.A303= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs377680010; called by muse, mutect2
- FLII | c.2802C>T p.Y934= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs951826406; ClinVar: likely benign; called by muse, mutect2
- GSN | c.2226G>C p.T742= | Silent (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- HDAC11 | c.789C>T p.L263= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs145222745; called by muse, mutect2, varscan2
- PDK4 | c.99C>T p.S33= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs1353983686; called by muse, mutect2, varscan2
- RP1L1 | c.2673G>T p.G891= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SIRT6 | c.348C>T p.D116= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs200245532; called by muse, mutect2, varscan2
- UCK1 | c.519C>T p.D173= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs772620410; called by muse, mutect2, varscan2
